Somatic mutation profile of tumor specimen HCM-BROD-0038-C41-86A (aliquot HCM-BROD-0038-C41-86A-01D-A80U-36) from HCMI case HCM-BROD-0038-C41, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Bone, NOS; Age at diagnosis: 16.2 years (5,911 days).
Specimen HCM-BROD-0038-C41-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28c7f9cb-7fa1-40c8-9e4b-1ace1ff68390.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0038-C41-10A (Blood Derived Normal), aliquot HCM-BROD-0038-C41-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20e146b9-33e3-4665-9553-f8f7b02b08d0

The open-access MAF lists 133 somatic variants for this specimen: 87 protein-altering or splice-affecting, 39 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 39, Nonsense Mutation 7, Intron 3, Splice Site 1, 5'Flank 1, 3'UTR 1, Frame Shift Ins 1, 3'Flank 1, Splice Region 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 594/594 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ADRA2B | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 828/1239 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280528454, COSV101337386; called by muse, varscan2
- ARHGEF26 | c.1124-1G>T p.X375_splice | Splice Site (SNP) | VAF 8/132 reads (6%) | catalogued as COSV100726483; called by muse, mutect2
- CLASP2 | c.2599C>G p.P867A | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV56288295; called by muse, mutect2, varscan2
- CSNK1E | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 70/414 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1187975483; called by muse, varscan2
- DIS3 | c.1971G>A p.R657= | Splice Region (SNP) | VAF 17/60 reads (28%) | catalogued as rs1383879280; called by muse, mutect2, varscan2
- KCNJ1 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60662527; called by muse, mutect2, varscan2
- KCNJ1 | c.715G>T p.G239* | Nonsense Mutation (SNP) | VAF 38/306 reads (12%) | catalogued as COSV100131422; called by muse, mutect2, varscan2
- NTRK3 | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 82/1504 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV58116866; called by muse, mutect2
- PDGFRA | c.2810C>T p.P937L | Missense Mutation (SNP) | VAF 89/308 reads (29%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.956); catalogued as rs267600188, COSV57266559; called by muse, mutect2, varscan2
- SLC4A11 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 35/341 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs760889152; called by muse, mutect2, varscan2
- SLCO4C1 | c.2071A>G p.K691E | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV60518103; called by muse, mutect2, varscan2
- WDR43 | c.1143G>A p.W381* | Nonsense Mutation (SNP) | VAF 17/106 reads (16%) | catalogued as COSV99943044; called by muse, mutect2, varscan2
- ABL1 | c.2989C>G p.P997A | Missense Mutation (SNP) | VAF 151/785 reads (19%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC092835.1 | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2
- ADAMTS17 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 82/500 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRL2 | c.2791G>C p.E931Q (on ENST00000370717 / NM_001366005.1; = p.E918Q on NM_012302.4) | Missense Mutation (SNP) | VAF 75/566 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AEBP1 | c.1125G>C p.E375D | Missense Mutation (SNP) | VAF 125/399 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- APOL5 | c.496A>T p.S166C | Missense Mutation (SNP) | VAF 60/486 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ARNTL | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 21/259 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- ASB2 | c.197A>T p.K66M | Missense Mutation (SNP) | VAF 119/497 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ASPSCR1 | c.956A>T p.D319V | Missense Mutation (SNP) | VAF 74/929 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2
- ATRX | c.3313C>G p.Q1105E | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- BICC1 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 141/324 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- C22orf31 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 97/430 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2orf78 | c.2275T>A p.S759T | Missense Mutation (SNP) | VAF 62/513 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- C6orf132 | c.595C>G p.P199A | Missense Mutation (SNP) | VAF 67/1264 reads (5%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- CCNP | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 15/412 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CD101 | c.2012T>C p.L671S | Missense Mutation (SNP) | VAF 45/589 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- CDC42BPG | c.917C>G p.A306G | Missense Mutation (SNP) | VAF 83/593 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- COL11A1 | c.5163T>G p.Y1721* | Nonsense Mutation (SNP) | VAF 35/710 reads (5%) | called by muse, mutect2
- CPSF2 | c.2194G>A p.G732R | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSMD1 | c.9906_9907insG p.C3303Vfs*12 (on ENST00000520002; = p.C3302Vfs*12 on NM_033225.6) | Frame Shift Ins (INS) | VAF 68/134 reads (51%) | called by mutect2, pindel*, varscan2
- DCAF15 | c.1472A>T p.N491I | Missense Mutation (SNP) | VAF 133/575 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DENND1C | c.1073G>T p.S358I | Missense Mutation (SNP) | VAF 64/315 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- ELAPOR2 | c.2519A>T p.N840I (on ENST00000450689 / NM_001142749.3; = p.N673I on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ELAPOR2 | c.706A>T p.K236* (on ENST00000450689 / NM_001142749.3; = p.K69* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 70/99 reads (71%) | called by muse, mutect2, varscan2
- ELF2 | c.1384A>G p.I462V (on ENST00000379550 / NM_001331036.2; = p.I402V on NM_006874.4) | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- FSBP | c.629T>A p.I210N | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- GABRG3 | c.1145G>A p.R382K | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.45); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- GDAP2 | c.57G>A p.W19* | Nonsense Mutation (SNP) | VAF 18/414 reads (4%) | called by muse, mutect2
- GDI2 | c.712T>C p.F238L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- ITPR3 | c.6371T>C p.I2124T | Missense Mutation (SNP) | VAF 112/416 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- KCNB2 | c.1837T>A p.F613I | Missense Mutation (SNP) | VAF 109/882 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- KCNK9 | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 98/902 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KDM4C | c.890G>C p.R297T | Missense Mutation (SNP) | VAF 43/43 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIAA1522 | c.2978C>G p.T993S (on ENST00000373480 / NM_001198972.2; = p.T1052S on NM_020888.3) | Missense Mutation (SNP) | VAF 161/436 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KIF4B | c.751A>T p.K251* | Nonsense Mutation (SNP) | VAF 85/331 reads (26%) | called by muse, mutect2, varscan2
- KIF5A | c.1048A>T p.K350* | Nonsense Mutation (SNP) | VAF 144/501 reads (29%) | called by muse, mutect2, varscan2
- KRT12 | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 73/473 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KRTAP10-9 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 200/1517 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- L3MBTL4 | c.1426T>G p.L476V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- LY6L | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 71/944 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.399); called by muse, mutect2
- MCCC2 | c.1378A>G p.R460G | Missense Mutation (SNP) | VAF 60/359 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH13 | c.2380G>T p.A794S | Missense Mutation (SNP) | VAF 84/1438 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.069); called by muse, mutect2
- MYH13 | c.2379G>C p.Q793H | Missense Mutation (SNP) | VAF 84/1448 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYH15 | c.23C>G p.T8R | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH2 | c.5189T>C p.I1730T | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); called by muse, mutect2
- NCOA6 | c.710C>G p.A237G | Missense Mutation (SNP) | VAF 60/688 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- NLRP3 | c.2458C>A p.L820M | Missense Mutation (SNP) | VAF 19/271 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NRSN1 | c.95A>C p.Q32P | Missense Mutation (SNP) | VAF 85/522 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR52E1 | c.743C>A p.T248N | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- OR5L2 | c.692C>G p.A231G | Missense Mutation (SNP) | VAF 107/353 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- OR8J1 | c.126C>G p.N42K | Missense Mutation (SNP) | VAF 28/635 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OXSM | c.94T>A p.F32I | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PCBP3 | c.233G>T p.R78M | Missense Mutation (SNP) | VAF 35/582 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHGA1 | c.1493G>T p.G498V | Missense Mutation (SNP) | VAF 79/369 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- PCLO | c.8267G>C p.R2756T | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by mutect2, varscan2
- PER3 | c.2500C>G p.Q834E | Missense Mutation (SNP) | VAF 58/784 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.13); called by muse, mutect2
- PGK2 | c.560G>C p.G187A | Missense Mutation (SNP) | VAF 59/1234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHF3 | c.1797G>C p.K599N | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- PLCH2 | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 273/480 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RPL3 | c.31C>T p.H11Y | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- SEMA3E | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH3GL1 | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 114/532 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2
- SLC35B2 | c.364T>G p.S122A | Missense Mutation (SNP) | VAF 29/1048 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- SSX5 | c.197C>A p.T66N (on ENST00000347757 / NM_175723.1; = p.T107N on NM_021015.4) | Missense Mutation (SNP) | VAF 56/56 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- TBC1D3F | c.135C>G p.N45K | Missense Mutation (SNP) | VAF 28/578 reads (5%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.464); called by muse, mutect2
- TBX21 | c.197C>A p.A66D | Missense Mutation (SNP) | VAF 125/1001 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- TIMM22 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 53/1345 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM147 | c.338T>G p.M113R | Missense Mutation (SNP) | VAF 108/687 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TXNDC11 | c.587A>G p.Y196C | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UPP1 | c.357G>C p.L119F | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF148 | c.1226A>T p.Q409L | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.242); called by muse, mutect2
- ZNF521 | c.3851del p.K1284Rfs*23 | Frame Shift Del (DEL) | VAF 90/226 reads (40%) | called by mutect2, pindel, varscan2
- ZNF563 | c.1030A>G p.K344E | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ZNF574 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 65/358 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ALKBH4 | c.768C>T p.I256= | Silent (SNP) | VAF 96/601 reads (16%) | called by muse, mutect2, varscan2
- ARFGEF1 | c.1185C>G p.V395= | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as COSV51609258; called by muse, mutect2
- C11orf96 | c.1059G>A p.K353= (on ENST00000339446; = p.K40= on NM_001145033.2) | Silent (SNP) | VAF 88/802 reads (11%) | called by muse, mutect2, varscan2
- CCER1 | c.747T>A p.T249= | Silent (SNP) | VAF 62/481 reads (13%) | called by muse, mutect2, varscan2
- CCSER2 | c.396G>A p.V132= | Silent (SNP) | VAF 70/70 reads (100%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.138C>A p.S46= | Silent (SNP) | VAF 36/262 reads (14%) | called by muse, mutect2, varscan2
- CRTC3 | c.1296C>T p.S432= | Silent (SNP) | VAF 149/1413 reads (11%) | called by muse, mutect2, varscan2
- CSMD1 | c.3423G>A p.K1141= (on ENST00000520002; = p.K1140= on NM_033225.6) | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs1282549982, COSV59331484; called by muse, mutect2, varscan2
- CTTNBP2 | c.150G>A p.G50= | Silent (SNP) | VAF 97/526 reads (18%) | called by muse, mutect2, varscan2
- DNAH9 | c.4213C>T p.L1405= | Silent (SNP) | VAF 109/685 reads (16%) | catalogued as rs1188338752; called by muse, mutect2, varscan2
- EPB41L2 | c.1716G>A p.G572= | Silent (SNP) | VAF 39/219 reads (18%) | catalogued as rs1314473455, COSV61355739; called by muse, mutect2, varscan2
- EQTN | c.300C>T p.V100= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- ERICH5 | c.765C>T p.P255= | Silent (SNP) | VAF 58/465 reads (12%) | called by muse, mutect2, varscan2
- FAXC | c.972G>A p.E324= | Silent (SNP) | VAF 43/231 reads (19%) | called by muse, mutect2, varscan2
- GPRC5B | c.261G>A p.K87= | Silent (SNP) | VAF 57/418 reads (14%) | called by muse, mutect2, varscan2
- GRB2 | c.630C>T p.V210= | Silent (SNP) | VAF 53/392 reads (14%) | called by muse, mutect2, varscan2
- HHATL | c.915C>A p.V305= | Silent (SNP) | VAF 107/461 reads (23%) | called by muse, mutect2, varscan2
- KCNE4 | c.150C>T p.A50= | Silent (SNP) | VAF 18/165 reads (11%) | catalogued as rs948209551; called by muse, mutect2, varscan2
- KCNQ3 | c.672C>T p.T224= | Silent (SNP) | VAF 101/932 reads (11%) | catalogued as rs768687450; called by muse, mutect2, varscan2
- KLHL32 | c.6G>T p.P2= | Silent (SNP) | VAF 202/202 reads (100%) | catalogued as rs145552576; called by muse, mutect2, varscan2
- LRP3 | c.282G>A p.E94= | Silent (SNP) | VAF 80/1470 reads (5%) | called by muse, mutect2
- MSRA | c.423C>T p.H141= | Silent (SNP) | VAF 97/97 reads (100%) | catalogued as rs367978405; called by muse, mutect2, varscan2
- NLRC3 | c.2430C>T p.S810= | Silent (SNP) | VAF 54/379 reads (14%) | catalogued as rs764998373, COSV100072265; called by muse, mutect2, varscan2
- NOD2 | c.201C>T p.S67= | Silent (SNP) | VAF 52/443 reads (12%) | called by muse, mutect2, varscan2
- NOS2 | c.2584C>T p.L862= | Silent (SNP) | VAF 13/406 reads (3%) | called by muse, mutect2
- PHC3 | c.477A>T p.L159= (on ENST00000494943 / NM_001308116.2; = p.L171= on NM_024947.4) | Silent (SNP) | VAF 51/347 reads (15%) | called by muse, mutect2, varscan2
- PKD1 | c.9942G>A p.R3314= | Silent (SNP) | VAF 13/406 reads (3%) | called by muse, mutect2
- QPCTL | c.687G>A p.K229= | Silent (SNP) | VAF 125/397 reads (31%) | called by muse, mutect2, varscan2
- RP1 | c.51T>A p.S17= | Silent (SNP) | VAF 59/508 reads (12%) | called by muse, mutect2, varscan2
- SGSM1 | c.2097G>A p.R699= | Silent (SNP) | VAF 95/481 reads (20%) | called by muse, mutect2, varscan2
- SSX5 | c.198C>A p.T66= (on ENST00000347757 / NM_175723.1; = p.T107= on NM_021015.4) | Silent (SNP) | VAF 56/56 reads (100%) | called by muse, mutect2, varscan2
- SYT14 | c.792G>T p.L264= | Silent (SNP) | VAF 36/151 reads (24%) | called by muse, mutect2, varscan2
- TMEM234 | c.87C>T p.S29= | Silent (SNP) | VAF 104/830 reads (13%) | catalogued as rs772673660; called by muse, mutect2, varscan2
- TRPC6 | c.2158C>T p.L720= | Silent (SNP) | VAF 25/118 reads (21%) | called by muse, mutect2
- UBAP2L | c.3078C>G p.A1026= | Silent (SNP) | VAF 101/573 reads (18%) | called by muse, mutect2, varscan2
- UGGT2 | c.702G>A p.V234= | Silent (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2, varscan2
- USP6 | c.3375C>T p.P1125= | Silent (SNP) | VAF 110/1272 reads (9%) | called by muse, mutect2
- ZNF469 | c.3292C>T p.L1098= (on ENST00000437464; = p.L1126= on NM_001367624.2) | Silent (SNP) | VAF 145/746 reads (19%) | called by muse, mutect2, varscan2
- ZSWIM5 | c.3267C>T p.A1089= | Silent (SNP) | VAF 87/474 reads (18%) | catalogued as rs752790011; called by muse, mutect2, varscan2
- COMMD10 | c.*479_*480dup | 3'UTR (INS) | VAF 8/71 reads (11%) | called by mutect2, pindel, varscan2
- CRMP1 | chr4:5889655 C>T | 5'Flank (SNP) | VAF 162/259 reads (63%) | called by muse, mutect2, varscan2
- FAM184A | c.1815+340A>G | Intron (SNP) | VAF 80/152 reads (53%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.242A>G | RNA (SNP) | VAF 174/340 reads (51%) | catalogued as rs768263281; called by muse, mutect2, varscan2
- LRGUK | c.1843+8486C>A | Intron (SNP) | VAF 96/452 reads (21%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1099194 A>T | 3'Flank (SNP) | VAF 145/1086 reads (13%) | called by muse, varscan2
- REXO2 | c.231+1019G>A | Intron (SNP) | VAF 25/201 reads (12%) | called by muse, mutect2, varscan2
